Somatic mutation profile of tumor specimen 0DS534 from CCDI case PBCHKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.6 years (585 days).
Specimen 0DS534: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99f94b6f-20f6-40d5-bcca-05b0bc91ec1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS541 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6eb58f2-2afd-491f-9f5b-f41e0fbc2cc2

The open-access MAF lists 24 somatic variants for this specimen: 12 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, Intron 2, 5'UTR 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BASP1 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 110/908 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs770798432, COSV59469820; called by muse, mutect2, varscan2
- CFAP299 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 122/779 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs150179610, COSV63880172; called by muse, mutect2, varscan2
- FNTA | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 125/2035 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs368301964; called by muse, mutect2
- NOM1 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 209/754 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs776824895; called by muse, mutect2, varscan2
- NPFFR2 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 201/658 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs200830127, COSV100440362; called by muse, mutect2, varscan2
- PNPLA3 | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 77/417 reads (18%) | catalogued as COSV53379800; called by muse, mutect2, varscan2
- ASCC3 | c.3442G>T p.V1148L | Missense Mutation (SNP) | VAF 126/948 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IPO8 | c.2378A>T p.N793I | Missense Mutation (SNP) | VAF 162/1112 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- LAMA1 | c.3554G>C p.S1185T | Missense Mutation (SNP) | VAF 62/495 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MINPP1 | c.872A>G p.D291G | Missense Mutation (SNP) | VAF 123/1528 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2
- MLXIP | c.508T>G p.W170G | Missense Mutation (SNP) | VAF 22/604 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- UBQLN3 | c.512T>G p.L171R | Missense Mutation (SNP) | VAF 100/426 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- ANK3 | c.624C>T p.I208= | Silent (SNP) | VAF 130/1708 reads (8%) | catalogued as rs775504143; called by muse, mutect2
- DACT1 | c.1146C>T p.G382= | Silent (SNP) | VAF 290/597 reads (49%) | catalogued as COSV60021406; called by muse, mutect2, varscan2
- GAL3ST1 | c.1266G>T p.R422= | Silent (SNP) | VAF 30/123 reads (24%) | called by mutect2, varscan2
- HEATR5B | c.3487C>A p.R1163= | Silent (SNP) | VAF 177/899 reads (20%) | catalogued as rs147083195, COSV51849794; called by muse, mutect2, varscan2
- POLR3H | c.309C>T p.F103= | Silent (SNP) | VAF 62/436 reads (14%) | called by muse, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 34/1400 reads (2%) | called by muse, mutect2
- ZNF862 | c.2712C>T p.G904= | Silent (SNP) | VAF 36/281 reads (13%) | called by muse, mutect2, varscan2
- ZXDA | c.2319A>T p.G773= | Silent (SNP) | VAF 26/688 reads (4%) | called by muse, mutect2
- ARHGEF28 | c.1024+18133G>C | Intron (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- CAVIN2 | c.-63G>A | 5'UTR (SNP) | VAF 7/67 reads (10%) | catalogued as rs1294895703; called by muse, mutect2, varscan2
- CCDC90B | c.469-17C>G | Intron (SNP) | VAF 90/1115 reads (8%) | called by muse, mutect2
- MADCAM1 | chr19:507411 G>T | 3'Flank (SNP) | VAF 12/73 reads (16%) | called by mutect2, varscan2
